TCGA case TCGA-YU-A94J — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e88112a-4db9-4714-a193-e823243a1d9c

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 19 years; Year of birth: 1990; Vital status: Alive.

Diagnoses (2)
1. Mixed germ cell tumor (the primary disease): ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 19.4 years (7,071 days); Year of diagnosis: 2009; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical N: N3; AJCC clinical M: M0; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T1; AJCC pathologic stage: Stage IIIB; IGCCCG stage: Intermediate Prognosis; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,675 days (4.6 years); Ajcc serum tumor markers: S2; Sites of involvement: Tunica Albuginea.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Post Adjuvant Therapy.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin; Treatment intent type: Adjuvant; Days to treatment start: 13 days; Days to treatment end: 91 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Mixed embryonal carcinoma and teratoma: Tissue or organ of origin: Testis, NOS; Laterality: Left; Classification of tumor: Synchronous primary; Age at diagnosis: 19.4 years (7,070 days); Days to diagnosis: -1 day; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 1,498 days (4.1 years); Disease response: Tumor Free.
- Days to follow up: 1,646 days (4.5 years); Disease response: Tumor Free.
- Days to follow up: 1,675 days (4.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -5: Lactate Dehydrogenase 590; Alpha Fetoprotein 2032; Human Chorionic Gonadotropin 3853.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YU-A94J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 390 mg.
  Slide TCGA-YU-A94J-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-YU-A94J-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YU-A94J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
